Somatic mutation profile of tumor specimen TCGA-G4-6586-01A (aliquot TCGA-G4-6586-01A-11D-1771-10) from TCGA case TCGA-G4-6586, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.0 years (27,020 days).
Specimen TCGA-G4-6586-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4632f2dd-a968-4086-9ea0-fcdda95cd885.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6586-10A (Blood Derived Normal), aliquot TCGA-G4-6586-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/793c568a-e287-46cd-a83e-58137874cd44

The open-access MAF lists 1,375 somatic variants for this specimen: 1,063 protein-altering or splice-affecting, 286 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 724, Silent 286, Frame Shift Del 215, Frame Shift Ins 45, Nonsense Mutation 36, Splice Site 17, Splice Region 13, RNA 11, In Frame Del 9, Intron 9, Translation Start Site 3, 3'UTR 2.

Variants (750 of 1,375; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSS1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140614802, CM162065; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP8A2 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 32/172 reads (19%) | catalogued as rs755133567, COSV54941586; ClinVar: likely pathogenic; called by muse, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMPR2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 64/231 reads (28%) | catalogued as rs137852753, CM010161, COSV65807978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 45/171 reads (26%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- F8 | c.5961dup p.E1988Rfs*4 | Frame Shift Ins (INS) | VAF 58/178 reads (33%) | catalogued as rs387906460; ClinVar: pathogenic; called by mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923dup p.L308Ffs*35 | Frame Shift Ins (INS) | VAF 50/206 reads (24%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 36/112 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 69/223 reads (31%) | catalogued as rs137853218, CM081410, COSV57192495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.539+1G>A p.X180_splice | Splice Site (SNP) | VAF 77/244 reads (32%) | catalogued as rs1566187856, CS002151, COSV57299313; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.8793del p.K2931Nfs*22 | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | catalogued as rs767871841, CD056854; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SCN5A | c.4070C>T p.A1357V (on ENST00000333535 / NM_198056.3; = p.A1356V on NM_000335.5) | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370588133, CM139917; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.14803C>T p.R4935* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as rs146733615, CM073405; ClinVar: pathogenic; called by muse, mutect2
- AAR2 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100299332; called by muse, mutect2, varscan2
- ABCA13 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs972957847, COSV101330078; called by muse, mutect2, varscan2
- ABCA13 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as COSV70026519; called by muse, mutect2, varscan2
- ABCA2 | c.2554T>C p.Y852H (on ENST00000614293; = p.Y822H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55798612; called by muse, mutect2, varscan2
- ABCA7 | c.1973C>A p.A658D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54025463, COSV54032840; called by muse, mutect2, varscan2
- ABCC1 | c.949T>G p.L317V | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60681978; called by muse, mutect2, varscan2
- ABI3BP | c.2317A>G p.T773A | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV52530509; called by muse, mutect2, varscan2
- AC011462.1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs535975575, COSV54195841; called by muse, mutect2, varscan2
- AC109583.1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs763693848, COSV59350388; called by muse, mutect2, varscan2
- ACADVL | c.277+2T>C p.X93_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as CS127072, COSV99138562; called by muse, mutect2, varscan2
- ACKR3 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV56020851; called by muse, mutect2, varscan2
- ACTA1 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CM012325, CM034511, CM045914, CX095261, COSV64203015; called by muse, mutect2, varscan2
- ACTN4 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1181047009, COSV99400311; called by muse, mutect2, varscan2
- ACTR3B | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759454179, COSV99753648; called by muse, mutect2, varscan2
- ACTRT3 | c.181A>G p.R61G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100377495; called by muse, mutect2, varscan2
- ACVR2B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs770339569, COSV61701613; called by muse, mutect2, varscan2
- ACY3 | c.456C>A p.C152* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | catalogued as COSV54828256; called by muse, mutect2, varscan2
- ADAM19 | c.1714T>C p.C572R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57424409; called by muse, mutect2, varscan2
- ADAM8 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69864406; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3251A>G p.N1084S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV65892312; called by muse, mutect2, varscan2
- ADCY5 | c.2858C>T p.T953M | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs372170924; called by muse, mutect2, varscan2
- ADGRD1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs375271891, COSV55438950, COSV55459066; called by muse, mutect2, varscan2
- ADGRL3 | c.3018T>C p.I1006= (on ENST00000506720 / NM_001322402.2; = p.I938= on NM_015236.6) | Splice Region (SNP) | VAF 114/389 reads (29%) | catalogued as COSV72229851; called by muse, mutect2, varscan2
- ADGRV1 | c.2626G>A p.V876I | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV67980133; called by muse, mutect2, varscan2
- ADK | c.830G>A p.R277Q (on ENST00000286621; = p.R260Q on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562751709, COSV54200858; called by muse, mutect2, varscan2
- AEBP1 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276713769, COSV56255997; called by muse, mutect2, varscan2
- AEN | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420847694, COSV60429027; called by muse, mutect2, varscan2
- AGBL1 | c.2041T>C p.W681R | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66852016; called by muse, mutect2, varscan2
- AGFG2 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV53544398; called by muse, mutect2, varscan2
- AGRN | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.21); catalogued as rs755903720, COSV65068194; called by muse, mutect2, varscan2
- AHDC1 | c.3235A>G p.T1079A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.124); catalogued as rs371317677; called by mutect2, varscan2
- AKAP13 | c.2591G>C p.S864T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV63450848; called by muse, mutect2, varscan2
- AKNA | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV56311502, COSV99800701; called by muse, mutect2, varscan2
- AKT1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs369198922; called by muse, mutect2, varscan2
- ALDOB | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 127/342 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV66397495; called by muse, mutect2, varscan2
- ALPK1 | c.2971T>C p.W991R | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99454295; called by muse, mutect2, varscan2
- ALPK3 | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs140424493, COSV99361111; called by muse, mutect2, varscan2
- ANK3 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377592480, COSV55048220; called by muse, mutect2, varscan2
- ANKLE1 | c.1445C>T p.A482V (on ENST00000394458; = p.A428V on NM_152363.6) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs146387346; called by muse, mutect2, varscan2
- ANKRD28 | c.2504A>G p.H835R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as rs772429036, COSV67517215; called by muse, mutect2, varscan2
- AOX1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs369320698; called by muse, mutect2, varscan2
- AP002512.3 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54405823; called by muse, mutect2, varscan2
- APBA3 | c.113A>G p.D38G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57462261; called by muse, mutect2, varscan2
- APLP1 | c.1714-1G>T p.X572_splice (on ENST00000221891 / NM_001024807.3; = p.X571_splice on NM_005166.4) | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99697724; called by muse, mutect2, varscan2
- APPL1 | c.1152+2T>C p.X384_splice | Splice Site (SNP) | VAF 68/208 reads (33%) | catalogued as COSV55700070; called by muse, mutect2, varscan2
- AQP7 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs1412196070, COSV53015661; called by muse, mutect2, varscan2
- ARAP2 | c.2692T>G p.F898V | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58283959; called by muse, mutect2, varscan2
- ARFGEF1 | c.4043G>A p.R1348H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250558374, COSV51604057; called by muse, mutect2, varscan2
- ARG2 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV55775477; called by muse, mutect2, varscan2
- ARHGAP31 | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51790034; called by muse, mutect2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | catalogued as rs751388541; called by mutect2, pindel, varscan2
- ARHGEF10L | c.1201T>C p.F401L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV99393032; called by muse, mutect2, varscan2
- ARHGEF11 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746467759, COSV59352836; called by muse, mutect2, varscan2
- ARHGEF12 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as COSV63103197; called by muse, mutect2, varscan2
- ARHGEF6 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.357); catalogued as rs368151602, COSV51688336, COSV51693824; called by muse, mutect2, varscan2
- ARID2 | c.186+1G>A p.X62_splice | Splice Site (SNP) | VAF 49/171 reads (29%) | catalogued as COSV57598605; called by muse, mutect2, varscan2
- ARL8A | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55342651, COSV55342877; called by muse, mutect2, varscan2
- ARSB | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs529444755, COSV53719930; called by muse, mutect2, varscan2
- ARSG | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 129/174 reads (74%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs754703816, COSV50929623; called by muse, mutect2, varscan2
- AS3MT | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as rs538040244, COSV54915999; called by muse, mutect2, varscan2
- ASB16 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs371159852, COSV53234228; called by muse, mutect2, varscan2
- ASH1L | c.5465del p.N1822Tfs*2 | Frame Shift Del (DEL) | VAF 93/329 reads (28%) | catalogued as COSV64205579; called by mutect2, pindel, varscan2
- ASXL2 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs986611894, COSV55455051; called by muse, mutect2, varscan2
- ATG4D | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs201291151, COSV57263887; called by muse, mutect2, varscan2
- ATP13A1 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs762199597, COSV52283414; called by muse, mutect2, varscan2
- ATP6AP2 | c.678T>G p.Y226* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV65797334; called by muse, mutect2, varscan2
- BAHD1 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1242917402, COSV69083698; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1307del p.P436Hfs*60 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs1405664842, COSV50055281; called by mutect2, pindel, varscan2
- BBS9 | c.1846C>T p.L616F (on ENST00000242067 / NM_001348036.1; = p.L576F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV54159662, COSV54175288; called by muse, mutect2, varscan2
- BCL9 | c.3527C>A p.P1176H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52341939; called by muse, mutect2, varscan2
- BEST1 | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV56444757; called by muse, mutect2, varscan2
- BICC1 | c.466A>T p.K156* | Nonsense Mutation (SNP) | VAF 50/163 reads (31%) | catalogued as COSV65857425; called by muse, mutect2, varscan2
- BIRC6 | c.11086A>G p.S3696G | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.237); catalogued as rs752759367, COSV70196633; called by muse, mutect2, varscan2
- BIRC6 | c.11951C>T p.A3984V | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66042799; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 68/194 reads (35%) | catalogued as rs747341586; called by mutect2, varscan2
- BLNK | c.451T>G p.S151A | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56409485; called by muse, mutect2, varscan2
- BMP2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs959542332, COSV66577171; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BOC | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.845); catalogued as rs964039345, COSV56348066; called by muse, mutect2
- BPNT2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389085; called by muse, mutect2, varscan2
- BRD7 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148401358, COSV67158853; called by muse, mutect2, varscan2
- BRPF3 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 49/152 reads (32%) | catalogued as COSV60206478, COSV60207618; called by muse, mutect2, varscan2
- BTK | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs868978699, COSV58117932; called by muse, mutect2, varscan2
- C16orf78 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs546860439, COSV54555346; called by muse, mutect2, varscan2
- C16orf82 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763981866; called by muse, mutect2, varscan2
- C19orf44 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.073); catalogued as rs758460163, COSV52222934; called by muse, mutect2, varscan2
- CABIN1 | c.4116C>T p.D1372= | Splice Region (SNP) | VAF 19/45 reads (42%) | catalogued as rs750110458, COSV54077665; called by muse, mutect2, varscan2
- CABP5 | c.433del p.R145Gfs*24 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | catalogued as rs769959570, COSV99506527; called by mutect2, pindel, varscan2
- CABYR | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59110473; called by muse, mutect2, varscan2
- CACHD1 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs754629617, COSV51549780; called by muse, mutect2, varscan2
- CACNA1H | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755831332, COSV61985722; called by muse, mutect2, varscan2
- CACNA1S | c.2560T>C p.Y854H | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV62937220; called by muse, mutect2, varscan2
- CACNA2D2 | c.2227C>T p.R743C (on ENST00000479441 / NM_001174051.3; = p.R736C on NM_006030.4) | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV56561356; called by muse, mutect2, varscan2
- CADM3 | c.442G>A p.A148T (on ENST00000368125 / NM_001127173.3; = p.A182T on NM_021189.5) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.034); catalogued as COSV63684404; called by muse, mutect2, varscan2
- CAMSAP1 | c.3434C>A p.P1145H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56720047; called by muse, mutect2, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | catalogued as rs201838505; called by mutect2, varscan2
- CAMSAP2 | c.3319C>A p.P1107T (on ENST00000236925 / NM_001297707.2; = p.P1096T on NM_203459.3) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV52667711; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPRIN2 | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV51831075; called by muse, mutect2, varscan2
- CAPS2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs138519970; called by muse, mutect2, varscan2
- CASP3 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as rs370247095; called by muse, mutect2, varscan2
- CASZ1 | c.3244A>G p.M1082V | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV59733013; called by muse, mutect2, varscan2
- CC2D1A | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV58781704; called by muse, mutect2, varscan2
- CCDC42 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs143164438; called by muse, mutect2, varscan2
- CCDC6 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54055294; called by muse, varscan2
- CCDC71 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs752522691, COSV58909890; called by muse, mutect2, varscan2
- CCDC93 | c.472T>C p.F158L | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as rs1364608510, COSV100098945; called by muse, mutect2, varscan2
- CCKAR | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV55160335; called by muse, mutect2, varscan2
- CCM2L | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52949334; called by muse, mutect2, varscan2
- CD5 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61717983, COSV61718259; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs762805003; called by pindel, varscan2
- CDC42EP4 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1378639523, COSV100231848; called by muse, mutect2, varscan2
- CDC42EP5 | c.391del p.Q131Rfs*12 | Frame Shift Del (DEL) | VAF 4/7 reads (57%) | catalogued as rs546021169; called by mutect2, varscan2
- CDCP1 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs1290344770, COSV56104181; called by muse, mutect2, varscan2
- CDH12 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1465712081, COSV66392941, COSV66421592; called by muse, mutect2, varscan2
- CDH13 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51786661, COSV51799691; called by muse, mutect2, varscan2
- CDH23 | c.6512G>A p.R2171H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs531513127, COSV56452048; called by muse, mutect2, varscan2
- CDH6 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV54065856; called by muse, mutect2, varscan2
- CDHR5 | c.1641dup p.G548Rfs*161 (on ENST00000358353 / NM_001171968.2; = p.G554Rfs*161 on NM_021924.5) | Frame Shift Ins (INS) | VAF 74/342 reads (22%) | catalogued as rs775160782; called by mutect2, pindel, varscan2
- CDK12 | c.3025T>C p.C1009R | Missense Mutation (SNP) | VAF 136/202 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70999660; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1356_1359del p.E454Kfs*11 | Frame Shift Del (DEL) | VAF 78/202 reads (39%) | catalogued as rs1445111778; called by mutect2, pindel, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 41/369 reads (11%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPK | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 108/346 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV54467386; called by muse, mutect2, varscan2
- CENPO | c.889A>C p.S297R | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV53165186; called by muse, mutect2, varscan2
- CETN3 | c.189dup p.A64Sfs*2 | Frame Shift Ins (INS) | VAF 38/107 reads (36%) | catalogued as rs763570929; called by mutect2, varscan2
- CFAP251 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV56608721; called by muse, mutect2, varscan2
- CHD6 | c.7252-2A>G p.X2418_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100951105; called by muse, mutect2, varscan2
- CHD6 | c.2038C>T p.L680F | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58555039; called by muse, mutect2, varscan2
- CHI3L1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs746382181, COSV55137359; called by muse, varscan2
- CHMP2B | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 107/299 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55461431; called by muse, mutect2, varscan2
- CHODL | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 86/235 reads (37%) | catalogued as rs561040335, COSV54731611; called by muse, varscan2
- CIAO3 | c.1035-3dup | Splice Region (INS) | VAF 17/85 reads (20%) | catalogued as rs757176359; called by mutect2, pindel, varscan2
- CIC | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV50550365; called by muse, mutect2, varscan2
- CILP2 | c.3073G>A p.G1025R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs148704674, COSV99364271; called by muse, mutect2, varscan2
- CLCN1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV58368165; called by muse, mutect2, varscan2
- CLSPN | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs748750595, COSV52047796; called by muse, mutect2, varscan2
- CNDP2 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761637739, COSV60839289; called by muse, mutect2, varscan2
- CNGA3 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.43); catalogued as COSV55622943, COSV99737058; called by muse, mutect2, varscan2
- CNKSR2 | c.1658-2A>G p.X553_splice | Splice Site (SNP) | VAF 87/254 reads (34%) | catalogued as COSV54251076; called by muse, mutect2, varscan2
- CNOT1 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57766289; called by muse, mutect2, varscan2
- CNOT2 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV57501511; called by muse, mutect2, varscan2
- CNOT4 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1279756794, COSV59650561; called by muse, mutect2, varscan2
- CNTN4 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs977295576, COSV68565725; called by muse, mutect2, varscan2
- COA8 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56027626; called by muse, mutect2, varscan2
- COL19A1 | c.2138A>G p.E713G | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59567836; called by muse, mutect2, varscan2
- COL1A2 | c.2933G>A p.R978H | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs559605075, COSV51954494; called by muse, mutect2, varscan2
- COL20A1 | c.3691G>A p.G1231S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1290553403, COSV58913227; called by muse, mutect2, varscan2
- COL23A1 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.685); catalogued as rs374627586, COSV66787099; called by muse, mutect2, varscan2
- COL27A1 | c.2618A>G p.K873R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61922753; called by muse, mutect2, varscan2
- COL4A1 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV65422655; called by muse, mutect2, varscan2
- COL5A3 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53407485; called by muse, mutect2, varscan2
- COL6A3 | c.8407G>A p.E2803K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781514010, COSV55082529; called by muse, mutect2, varscan2
- COL7A1 | c.8782C>T p.R2928C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1225933099, COSV56476130; called by muse, mutect2, varscan2
- COL7A1 | c.5120G>A p.R1707Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.377); catalogued as rs747945597, COSV60394783; called by muse, mutect2, varscan2
- CORO6 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV61470275; called by muse, mutect2, varscan2
- COX6C | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs746221706, COSV52553295; called by muse, varscan2
- CPSF6 | c.857A>G p.Q286R | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV57013147; called by muse, mutect2, varscan2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as COSV51715473; called by mutect2, pindel, varscan2
- CREB3L1 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as rs774678396, COSV55830581; called by muse, mutect2, varscan2
- CRISP2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776489954, COSV59253667; called by muse, mutect2, varscan2
- CRMP1 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560508405, COSV61478684; called by muse, mutect2, varscan2
- CROCC | c.5000G>A p.R1667H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1180225994, COSV65010670; called by muse, mutect2, varscan2
- CRTAC1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546782945, COSV53998548; called by muse, mutect2, varscan2
- CRTC1 | c.1277dup p.E427Rfs*24 | Frame Shift Ins (INS) | VAF 51/165 reads (31%) | catalogued as rs760791352; called by mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 44/132 reads (33%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSF2RB | c.281G>T p.R94M | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53256202; called by muse, mutect2, varscan2
- CSMD3 | c.9058T>C p.S3020P (on ENST00000297405 / NM_001363185.1; = p.S2851P on NM_052900.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99836597; called by muse, mutect2, varscan2
- CSMD3 | c.7947G>T p.L2649F (on ENST00000297405 / NM_001363185.1; = p.L2545F on NM_052900.3) | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV52124872; called by muse, mutect2, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | catalogued as rs758642867; called by mutect2, pindel, varscan2
- CUL3 | c.2027C>T p.T676I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV52362309; called by muse, mutect2, varscan2
- CUX2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs370159212; called by muse, mutect2, varscan2
- CUX2 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs776222215, COSV55626545; called by muse, mutect2, varscan2
- CWC22 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs375318426; called by muse, mutect2, varscan2
- CXCR4 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as COSV54010775; called by muse, mutect2, varscan2
- CYC1 | c.276dup p.S93Qfs*26 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs756254049; called by mutect2, varscan2
- CYFIP2 | c.3344C>T p.S1115F (on ENST00000616178 / NM_001291722.2; = p.S1090F on NM_014376.4) | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59030478; called by muse, mutect2
- CYP4F12 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs150856722, COSV61172750; called by muse, mutect2, varscan2
- CYP4F2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1388353329, COSV55620300; called by muse, mutect2, varscan2
- CYTIP | c.848A>C p.E283A | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV51632324; called by muse, mutect2, varscan2
- DAB2IP | c.212C>T p.T71M (on ENST00000408936; = p.T43M on NM_032552.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs199540285, COSV52255777; called by muse, mutect2, varscan2
- DACH2 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.018); catalogued as rs375711615, COSV64163746; called by muse, mutect2, varscan2
- DAPK3 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV56662389; called by muse, mutect2, varscan2
- DAZAP1 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV51831845, COSV51836283; called by muse, varscan2
- DCAF4 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs139428330; called by muse, mutect2, varscan2
- DCAF4L1 | c.173del p.K58Rfs*31 | Frame Shift Del (DEL) | VAF 62/207 reads (30%) | catalogued as COSV60786427; called by mutect2, pindel, varscan2
- DCC | c.3764C>T p.T1255M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs775848107, COSV101473552, COSV71434183; called by muse, mutect2, varscan2
- DCHS1 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as rs201800543, COSV100202774, COSV55031991; called by muse, varscan2
- DCHS1 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV55032002; called by muse, varscan2
- DCTN1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62619770; called by muse, mutect2, varscan2
- DDX11 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 137/490 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52500980; called by muse, mutect2, varscan2
- DDX59 | c.408_410del p.L137del | In Frame Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs769594366; called by pindel, varscan2
- DEFB132 | c.127dup p.E43Gfs*24 | Frame Shift Ins (INS) | VAF 29/97 reads (30%) | catalogued as rs776618282; called by mutect2, pindel, varscan2
- DENND2B | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs547568595, COSV58201965; called by muse, mutect2, varscan2
- DENND2B | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142799946, COSV58201975; called by muse, mutect2, varscan2
- DENND3 | c.3031G>A p.G1011S | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761083003, COSV99371097; called by muse, mutect2, varscan2
- DENND5A | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs148317700; called by muse, mutect2, varscan2
- DHX16 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64563328; called by muse, mutect2, varscan2
- DHX30 | c.2230G>A p.V744M (on ENST00000445061 / NM_138615.3; = p.V705M on NM_014966.3) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1014435845, COSV53136086; called by muse, mutect2, varscan2
- DIDO1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1264359122, COSV56615891; called by muse, mutect2, varscan2
- DIMT1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52232961; called by muse, mutect2, varscan2
- DIP2C | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs1454127875, COSV55149729; called by muse, mutect2, varscan2
- DLX2 | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as COSV99308586, COSV99308667; called by muse, mutect2, varscan2
- DMD | c.10085C>T p.P3362L | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1569423459, COSV58896538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.2905G>A p.V969I | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs750582245, COSV63740182; called by muse, mutect2, varscan2
- DMRT3 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs369325576; called by muse, mutect2, varscan2
- DNAH10 | c.9776T>C p.M3259T (on ENST00000409039; = p.M3198T on NM_207437.3) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV68989550; called by muse, mutect2, varscan2
- DNAH2 | c.12301T>G p.L4101V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV66717449; called by muse, mutect2, varscan2
- DNAH3 | c.8309C>T p.A2770V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178781340, COSV54508926; called by muse, mutect2, varscan2
- DNAJA3 | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52161162; called by muse, mutect2, varscan2
- DNAJB12 | c.1079G>A p.R360Q (on ENST00000338820; = p.R326Q on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.976); catalogued as rs1425144466, COSV58759872; called by muse, mutect2, varscan2
- DNAJB5 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs35837382; called by muse, varscan2
- DNAJC13 | c.4998del p.G1667Vfs*22 | Frame Shift Del (DEL) | VAF 70/248 reads (28%) | catalogued as COSV53444955; called by mutect2, pindel, varscan2
- DOCK8 | c.4450A>G p.T1484A | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV66618523; called by muse, varscan2
- DOP1A | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs748571753, COSV52707750; called by muse, mutect2, varscan2
- DOP1A | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765139261, COSV52707072; called by muse, mutect2, varscan2
- DOP1A | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99382140; called by muse, mutect2, varscan2
- DPH1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs371816907, COSV53983881; called by muse, mutect2, varscan2
- DPP6 | c.1602G>T p.E534D (on ENST00000377770 / NM_001364500.2; = p.E472D on NM_001936.5) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100126007; called by muse, mutect2, varscan2
- DPYSL2 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs374825617; called by muse, mutect2, varscan2
- DRD5 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV58577032; called by muse, mutect2, varscan2
- DSCAML1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.068); catalogued as rs1489468554, COSV58384394; called by muse, mutect2, varscan2
- DSPP | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); catalogued as rs773490979, COSV56808618; called by muse, mutect2, varscan2
- DTX4 | c.1165A>C p.T389P | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV57089121; called by muse, mutect2, varscan2
- DVL2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs780268199, COSV50034912; called by muse, mutect2, varscan2
- E2F7 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59738138; called by muse, mutect2, varscan2
- EBF2 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs1467349351, COSV68776604; called by muse, mutect2, varscan2
- EFCAB6 | c.3935C>T p.P1312L | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53059696; called by muse, mutect2, varscan2
- EFCC1 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.031); catalogued as rs567338824, COSV71401788; called by muse, mutect2, varscan2
- EFNA4 | c.535dup p.D179Gfs*65 | Frame Shift Ins (INS) | VAF 34/97 reads (35%) | catalogued as rs754580525; called by mutect2, varscan2
- EHMT1 | c.3461A>T p.E1154V | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV71777411; called by muse, mutect2, varscan2
- EIF5 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99384871; called by muse, varscan2
- ELF3 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV62837641; called by muse, mutect2, varscan2
- ELN | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.043); catalogued as rs1563783035, COSV52708017, COSV52716031; called by muse, mutect2, varscan2
- ELP1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV59828981; called by muse, mutect2, varscan2
- EMILIN2 | c.1562C>A p.A521E | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV54421898; called by muse, mutect2, varscan2
- ENC1 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56628831; called by muse, mutect2, varscan2
- ENPP2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs767465276, COSV50010797; called by muse, mutect2, varscan2
- ENPP4 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs372499430; called by muse, mutect2, varscan2
- EPB41L4A | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54864384; called by muse, mutect2, varscan2
- EPHA4 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV56028439; called by muse, mutect2, varscan2
- EPHA6 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67563189, COSV67575954; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 14/78 reads (18%) | catalogued as rs756461692; called by mutect2, varscan2
- ERC2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201020011, COSV55601042; called by muse, mutect2, varscan2
- ERMARD | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs776602765, COSV64647688, COSV64648912; called by muse, mutect2, varscan2
- ERN2 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1442722511, COSV55622114; called by muse, mutect2, varscan2
- ESRRG | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs765802592, COSV63152410; called by muse, mutect2, varscan2
- ESYT3 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67440433; called by muse, mutect2, varscan2
- EVC2 | c.1999C>T p.L667F | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60389033; called by muse, mutect2, varscan2
- F7 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as CM090299, COSV100660927; called by mutect2, varscan2
- F7 | c.647del p.G216Afs*17 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs748874982; called by mutect2, pindel, varscan2
- FAHD2A | c.842dup p.G282Rfs*17 | Frame Shift Ins (INS) | VAF 50/150 reads (33%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM135B | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.325); catalogued as rs543824232, COSV52711396, COSV99425264; called by muse, mutect2, varscan2
- FAM161B | c.1607dup p.N537Efs*5 (on ENST00000651776; = p.N474Efs*5 on NM_152445.3) | Frame Shift Ins (INS) | VAF 89/262 reads (34%) | catalogued as rs1439977823; called by mutect2, varscan2
- FAM187B | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100220013; called by muse, mutect2
- FAM47B | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs777489815, COSV61452405; called by muse, mutect2, varscan2
- FAM47C | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.509); catalogued as rs1427563293, COSV100792436; called by muse, mutect2, varscan2
- FAM53A | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs369257679; called by muse, mutect2, varscan2
- FAM83H | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV66353581; called by muse, mutect2, varscan2
- FANCM | c.5579G>A p.R1860H | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776506025, COSV57497797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.12434C>T p.A4145V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.814); catalogued as COSV53085976; called by muse, mutect2, varscan2
- FAT4 | c.2014A>G p.M672V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs772308456, COSV67882523; called by muse, mutect2, varscan2
- FAT4 | c.8974A>G p.T2992A | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV100628868; called by muse, mutect2, varscan2
- FBN2 | c.7659dup p.F2554Vfs*4 | Frame Shift Ins (INS) | VAF 29/97 reads (30%) | catalogued as rs748600284; called by mutect2, varscan2
- FBXL15 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV50042528; called by muse, mutect2, varscan2
- FBXO31 | c.1318T>C p.C440R | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV61148055; called by muse, mutect2, varscan2
- FBXO43 | c.1826T>C p.L609P | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV71053495; called by muse, mutect2, varscan2
- FCGBP | c.11278C>T p.R3760W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs753209481; called by muse, mutect2, varscan2
- FCSK | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs569139301, COSV55368468; called by muse, mutect2, varscan2
- FGD1 | c.2576del p.P859Lfs*4 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | catalogued as rs768230678; called by mutect2, pindel, varscan2
- FGF10 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52932686; called by muse, mutect2, varscan2
- FGF12 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV53152374, COSV53155258, COSV53158085; called by muse, mutect2, varscan2
- FLG | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 166/475 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs756351291, COSV64235927; called by muse, mutect2, varscan2
- FLNA | c.7825G>A p.V2609M (on ENST00000369850 / NM_001110556.2; = p.V2601M on NM_001456.3) | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV61039008; called by muse, mutect2, varscan2
- FLOT2 | c.1251A>G p.I417M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV67528883; called by muse, mutect2, varscan2
- FNIP1 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 160/472 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761595163, COSV57194596; called by muse, mutect2, varscan2
- FOLR1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100398564; called by muse, mutect2, varscan2
- FOSL1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs564101721, COSV57027597; called by muse, mutect2, varscan2
- FOXA2 | c.86G>T p.S29I (on ENST00000377115 / NM_153675.3; = p.S35I on NM_021784.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV65795788; called by muse, mutect2, varscan2
- FOXD3 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942900; called by muse, mutect2, varscan2
- FOXO4 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58574882; called by muse, mutect2, varscan2
- FOXR1 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs368571294; called by muse, mutect2, varscan2
- FOXRED2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553832344, COSV53399112; called by muse, mutect2, varscan2
- FRAS1 | c.8972C>T p.T2991M | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376261766; called by muse, mutect2, varscan2
- FREM2 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1566101813, COSV99749144; called by muse, mutect2
- FREM2 | c.2383G>A p.V795M | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs369187680; called by muse, mutect2, varscan2
- FRMPD4 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV66212221; called by muse, mutect2, varscan2
- FTCD | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs147140166; called by muse, mutect2, varscan2
- FTSJ3 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs143751811; called by muse, mutect2, varscan2
- FUT1 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs748679094, COSV59567651; called by muse, mutect2, varscan2
- FUT7 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs751960711, COSV55798617; called by muse, mutect2, varscan2
- FXR1 | c.1745G>A p.G582D | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV59761563; called by muse, mutect2, varscan2
- FXR2 | c.1619dup p.A541Sfs*14 | Frame Shift Ins (INS) | VAF 22/79 reads (28%) | catalogued as rs753982098; called by mutect2, varscan2
- FZD7 | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV53808554; called by muse, mutect2, varscan2
- GALNT16 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV61884927; called by muse, mutect2, varscan2
- GALNT3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs377319905; called by muse, mutect2, varscan2
- GANC | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 47/165 reads (28%) | PolyPhen benign (0.006); catalogued as rs757173638, COSV58807826; called by muse, mutect2, varscan2
- GAPDHS | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55880102; called by muse, mutect2, varscan2
- GBA2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs760492879, COSV62305411; called by muse, mutect2, varscan2
- GCFC2 | c.1644dup p.V549Sfs*42 | Frame Shift Ins (INS) | VAF 38/163 reads (23%) | catalogued as rs757231207; called by mutect2, pindel, varscan2
- GDF2 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs138904328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GEMIN4 | c.2158T>C p.C720R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56745207; called by muse, mutect2, varscan2
- GEMIN5 | c.3434A>G p.Y1145C | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.671); catalogued as COSV53558878; called by muse, mutect2, varscan2
- GFI1B | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765068455, COSV59743963; called by muse, mutect2, varscan2
- GHDC | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs200346068, COSV56987012; called by muse, mutect2, varscan2
- GIT1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs374787973; called by muse, varscan2
- GJB4 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs778397300, COSV58355656, COSV58357162; called by muse, mutect2, varscan2
- GLI3 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as rs774858780, COSV67886144; called by muse, mutect2, varscan2
- GLRA2 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 64/181 reads (35%) | catalogued as COSV54337228; called by muse, mutect2, varscan2
- GLRA2 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54337247; called by muse, mutect2, varscan2
- GLUD2 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as COSV60151490; called by muse, mutect2, varscan2
- GMPS | c.2037G>A p.M679I | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs1298474847, COSV99903202; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 42/133 reads (32%) | catalogued as rs1022402829; called by mutect2, varscan2
- GP2 | c.1601C>A p.A534D (on ENST00000381362 / NM_001007240.3; = p.A531D on NM_001502.4) | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56892455; called by muse, mutect2, varscan2
- GPATCH2L | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as rs747637759, COSV55047222; called by muse, mutect2, varscan2
- GPN2 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV64651594, COSV64651706; called by muse, mutect2, varscan2
- GPR26 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52933090; called by muse, mutect2, varscan2
- GRID1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201655919, COSV60017942; called by muse, mutect2, varscan2
- GRIK2 | c.664A>T p.K222* | Nonsense Mutation (SNP) | VAF 36/178 reads (20%) | catalogued as COSV59717815; called by muse, varscan2
- GRIN1 | c.1486_1488del p.K496del | In Frame Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1231157661; called by pindel, varscan2
- GRIN2A | c.3862C>T p.R1288C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58024367; called by muse, mutect2, varscan2
- GRIN2B | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs778695605, COSV74205086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 39/70 reads (56%) | catalogued as rs754199513; called by mutect2, varscan2
- GSK3B | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347660914, COSV51771998; called by muse, mutect2, varscan2
- GTPBP2 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs779230466, COSV61075831; called by muse, mutect2, varscan2
- GUCY1A2 | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780369830, COSV56480463; called by muse, mutect2, varscan2
- GUCY2D | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs144151076; called by muse, mutect2, varscan2
- GYPC | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as COSV52145312; called by muse, mutect2, varscan2
- H4C13 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as rs1217961483, COSV60693386; called by muse, mutect2, varscan2
- H6PD | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs781605545, COSV66230477; called by muse, mutect2, varscan2
- HAS2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as rs1312779160, COSV58266803; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HCFC2 | c.1063+2T>C p.X355_splice | Splice Site (SNP) | VAF 14/90 reads (16%) | catalogued as COSV57558177; called by muse, varscan2
- HCN2 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV52112994; called by muse, mutect2, varscan2
- HDLBP | c.2997G>A p.M999I | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as COSV60492853; called by muse, mutect2, varscan2
- HECA | c.1376G>A p.C459Y | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62768702; called by muse, mutect2, varscan2
- HECTD4 | c.6175A>G p.R2059G | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV66388262; called by muse, mutect2, varscan2
- HELLS | c.1892T>C p.L631S | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99492131; called by muse, mutect2, varscan2
- HERC5 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV52037951; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 65/245 reads (27%) | catalogued as rs199474609; called by mutect2, varscan2
- HLA-A | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs41550912, COSV65138258; called by muse, varscan2
- HMCN1 | c.4436G>T p.G1479V | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54884045, COSV54922906; called by muse, mutect2, varscan2
- HOOK2 | c.1604T>A p.I535N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.276); catalogued as COSV53401567; called by muse, mutect2, varscan2
- HSF1 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.384); catalogued as COSV60047156; called by muse, mutect2, varscan2
- HSPA12A | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs782629136, COSV65021172; called by muse, mutect2, varscan2
- HSPA2 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.377); catalogued as COSV55968995; called by muse, mutect2, varscan2
- HTR1A | c.188T>C p.L63S | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60500157; called by muse, mutect2, varscan2
- HTR2B | c.1275dup p.K426* | Frame Shift Ins (INS) | VAF 96/311 reads (31%) | catalogued as rs760960108; called by mutect2, pindel, varscan2
- HUNK | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs769777844, COSV54225525; called by muse, mutect2, varscan2
- HYAL3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56496985; called by muse, mutect2, varscan2
- IFT27 | c.391C>T p.R131* (on ENST00000433985 / NM_001363003.2; = p.R130* on NM_006860.5) | Nonsense Mutation (SNP) | VAF 43/102 reads (42%) | catalogued as rs374999621; called by muse, mutect2, varscan2
- IGF2BP2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs200027200; called by muse, mutect2, varscan2
- IGKV2D-29 | c.177T>A p.Y59* | Nonsense Mutation (SNP) | VAF 130/349 reads (37%) | catalogued as COSV101534381; called by muse, mutect2, varscan2
- IGSF1 | c.2278A>G p.K760E | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV63836563; called by muse, mutect2, varscan2
- IGSF10 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV56782529; called by muse, mutect2, varscan2
- IL11 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748079395, COSV52772208; called by muse, mutect2, varscan2
- IL2RG | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 82/236 reads (35%) | catalogued as COSV52147557; called by muse, mutect2, varscan2
- ILKAP | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as COSV54517590; called by muse, mutect2, varscan2
- INPP5D | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748315737, COSV64035937; called by muse, mutect2, varscan2
- INSC | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs552439006, COSV65409276; called by muse, mutect2, varscan2
- INTS1 | c.4361C>T p.S1454L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs370490865; called by muse, mutect2, varscan2
- INTS5 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as COSV57950627; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQSEC3 | c.2420A>C p.E807A (on ENST00000538872 / NM_001170738.2; = p.E504A on NM_015232.1) | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV58281710; called by muse, mutect2, varscan2
- ITGA11 | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs201176891; called by muse, mutect2, varscan2
- ITGA5 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.503); catalogued as rs375602887; called by muse, mutect2, varscan2
- ITGA7 | c.2609G>A p.G870D (on ENST00000555728; = p.G826D on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV57692799; called by muse, mutect2, varscan2
- ITIH2 | c.1403A>C p.E468A | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV64432338; called by muse, mutect2, varscan2
- ITPKB | c.2824G>T p.D942Y | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV55258328, COSV99684554; called by muse, mutect2, varscan2
- ITPRID1 | c.1915T>G p.S639A | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60071558; called by muse, mutect2, varscan2
- JAK1 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV61088382; called by muse, mutect2, varscan2
- JAK3 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780084832, COSV101512979, COSV71685780; called by muse, mutect2, varscan2
- JPH2 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1569226748, COSV60696460; called by muse, mutect2, varscan2
- KALRN | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs749891135, COSV53755839; called by muse, mutect2, varscan2
- KATNIP | c.2412G>T p.R804S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as rs781055909, COSV99851314; called by muse, mutect2, varscan2
- KATNIP | c.2735del p.G912Dfs*85 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as COSV99850113; called by mutect2, pindel, varscan2
- KAZN | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs748019374, COSV63207069; called by muse, mutect2, varscan2
- KCMF1 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV69053336; called by muse, mutect2, varscan2
- KCNG2 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV60266993; called by muse, mutect2, varscan2
- KCNH7 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV59789456, COSV59792787; called by muse, mutect2, varscan2
- KCNK12 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs1234511570, COSV100009838; called by muse, mutect2
- KCNQ5 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs776285517, COSV59652775; called by muse, mutect2, varscan2
- KCNV1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1438034311, COSV99819160; called by muse, mutect2, varscan2
- KCTD12 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV100499730; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KHDRBS2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs200792688, COSV99834485; called by muse, varscan2
- KIAA0586 | c.1491A>C p.K497N (on ENST00000619416 / NM_001244190.2; = p.K512N on NM_014749.5) | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV54172511; called by muse, mutect2, varscan2
- KIAA0930 | c.778C>T p.R260* (on ENST00000336156 / NM_001009880.2; = p.R265* on NM_015264.2) | Nonsense Mutation (SNP) | VAF 31/94 reads (33%) | catalogued as COSV52662419; called by muse, mutect2, varscan2
- KIAA1210 | c.4148C>A p.A1383D | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV68175999; called by muse, mutect2, varscan2
- KIF19 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 41/50 reads (82%) | catalogued as COSV63428992; called by muse, mutect2, varscan2
- KIF20B | c.2944A>G p.I982V (on ENST00000371728 / NM_001284259.2; = p.I942V on NM_016195.4) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99590188; called by muse, mutect2, varscan2
- KIF21B | c.4843G>A p.V1615I (on ENST00000422435 / NM_001252100.2; = p.V1602I on NM_017596.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.311); catalogued as rs200570033, COSV59753995; called by muse, mutect2
- KIF26A | c.3574C>T p.P1192S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100181224; called by muse, mutect2
- KIF26B | c.5089G>A p.A1697T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV63636080; called by muse, mutect2
- KIF4A | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs35473790, COSV65541997; called by muse, mutect2, varscan2
- KIT | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs376469897, COSV55391289, COSV55422608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIT | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV55392060; called by muse, mutect2, varscan2
- KLC2 | c.512A>G p.E171G | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV57581842; called by muse, mutect2, varscan2
- KLK9 | c.448del p.A150Pfs*121 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs777838989; called by mutect2, pindel, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2C | c.3292G>T p.D1098Y | Missense Mutation (SNP) | VAF 109/325 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV51401005; called by muse, mutect2, varscan2
- KMT2D | c.13451G>A p.R4484Q | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.644); catalogued as rs1480605988, COSV56417474; called by muse, mutect2, varscan2
- KMT2E | c.3125C>A p.P1042H | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV57570627; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT74 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV59770757; called by muse, mutect2, varscan2
- KRTAP26-1 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.134); catalogued as COSV62128568; called by muse, mutect2, varscan2
- KRTAP4-12 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs1373505971, COSV67458223; called by muse, mutect2, varscan2
- KSR2 | c.248A>T p.N83I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV60369002, COSV60388004; called by muse, mutect2, varscan2
- L3HYPDH | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV54198626; called by muse, mutect2, varscan2
- LARS1 | c.2938C>T p.P980S (on ENST00000394434 / NM_020117.11; = p.P953S on NM_016460.3) | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV50972790; called by muse, mutect2, varscan2
- LCA5L | c.595A>C p.I199L | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV55744251; called by muse, mutect2, varscan2
- LCP2 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1254716876, COSV50447424; called by muse, mutect2, varscan2
- LEPROT | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1438700596, COSV100756142, COSV60749202; called by muse, mutect2, varscan2
- LIG4 | c.2448C>G p.H816Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.156); catalogued as COSV63596618; called by muse, mutect2, varscan2
- LMAN1L | c.777T>C p.V259= | Splice Region (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100547730; called by muse, mutect2, varscan2
- LMCD1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs1263611922, COSV50087527; called by muse, mutect2, varscan2
- LOXL4 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs761482236, COSV53255020; called by muse, mutect2, varscan2
- LPA | c.2731G>A p.V911I | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs932171816, COSV60298455, COSV60306182; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 35/147 reads (24%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRRC15 | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV61649707; called by muse, mutect2, varscan2
- LTBP4 | c.2507A>G p.D836G (on ENST00000308370 / NM_001042544.1; = p.D799G on NM_003573.2) | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV52577721; called by muse, mutect2, varscan2
- LUZP1 | c.1682C>G p.S561C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV56499131; called by muse, mutect2, varscan2
- LYZL2 | c.184G>T p.G62C (on ENST00000375318; = p.G16C on NM_183058.3) | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV64683852; called by muse, mutect2, varscan2
- MACROH2A2 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 43/122 reads (35%) | catalogued as COSV64706594; called by muse, mutect2, varscan2
- MAGEB6 | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.109); catalogued as COSV66872001; called by muse, mutect2, varscan2
- MAGEC1 | c.1841G>T p.S614I | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV53569391, COSV53572267; called by muse, mutect2, varscan2
- MAGEC1 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as COSV53568169, COSV53569400; called by muse, mutect2, varscan2
- MAGEC3 | c.134del p.K45Rfs*15 | Frame Shift Del (DEL) | VAF 51/155 reads (33%) | catalogued as rs1281321536; called by mutect2, pindel, varscan2
- MAGED2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 162/490 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV54498156, COSV99514343; called by muse, varscan2
- MAN2B1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs752541064, COSV55470615; called by muse, mutect2, varscan2
- MAP3K1 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1034896455, COSV101265994; called by muse, mutect2, varscan2
- MARF1 | c.2720del p.K907Sfs*6 | Frame Shift Del (DEL) | VAF 54/204 reads (26%) | catalogued as rs1303520043; called by mutect2, varscan2
- MARK1 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs745932586, COSV100857307; called by muse, mutect2, varscan2
- MAST1 | c.4462C>T p.R1488C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV52242537; called by muse, mutect2, varscan2
- MCF2 | c.47A>G p.N16S | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100644831; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MDH2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782472423, COSV59883891; called by muse, mutect2, varscan2
- ME2 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.531); catalogued as rs749019256, COSV58422523; called by muse, mutect2, varscan2
- MECP2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs782805738, COSV57652311; called by muse, mutect2, varscan2
- MED12L | c.3356C>T p.A1119V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs200564154, COSV56371642; called by muse, mutect2, varscan2
- MED16 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs900635805, COSV54124153; called by muse, mutect2, varscan2
- MED4 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.326); catalogued as rs144201204, COSV51638827, COSV99320088; called by muse, mutect2, varscan2
- MELK | c.1796A>G p.Q599R | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV53197507; called by muse, mutect2, varscan2
- MFSD11 | c.639C>T p.N213= | Splice Region (SNP) | VAF 38/53 reads (72%) | catalogued as rs150713383; called by muse, mutect2, varscan2
- MGAT3 | c.384del p.P130Rfs*24 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs768261467, COSV57864436; called by mutect2, pindel, varscan2
- MGAT5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 39/179 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV56094641; called by muse, mutect2, varscan2
- MIA | c.262-2A>G p.X88_splice | Splice Site (SNP) | VAF 32/88 reads (36%) | catalogued as COSV54571023; called by muse, mutect2, varscan2
- MIA3 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60510626; called by muse, mutect2, varscan2
- MICAL2 | c.4003G>T p.G1335* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as COSV56284639, COSV99812379; called by muse, mutect2, varscan2
- MITF | c.1495G>A p.G499R (on ENST00000448226 / NM_006722.3; = p.G399R on NM_000248.4) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs531830542, CM163269, COSV58830336; called by muse, mutect2, varscan2
- MMP1 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59509607; called by muse, mutect2, varscan2
- MMP10 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139185475; called by muse, mutect2, varscan2
- MOB3A | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.93); catalogued as rs772988384, COSV63865407; called by muse, mutect2, varscan2
- MORC4 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55241926; called by muse, mutect2
- MOS | c.379A>C p.T127P | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV100322854; called by muse, mutect2, varscan2
- MOV10 | c.2498A>G p.Y833C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53516887; called by muse, mutect2, varscan2
- MRAP | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1222205058, COSV100353343, COSV57936539; called by muse, mutect2, varscan2
- MRGPRX1 | c.560del p.L187Yfs*13 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | catalogued as rs1390190298; called by mutect2, varscan2
- MROH5 | c.3682C>A p.R1228S | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.01); catalogued as COSV100267281; called by muse, mutect2, varscan2
- MSH5 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | catalogued as COSV65172644; called by muse, mutect2, varscan2
- MSL3 | c.842A>G p.Q281R (on ENST00000312196 / NM_078629.4; = p.Q115R on NM_006800.4) | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56492043; called by muse, mutect2, varscan2
- MSS51 | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV55018722; called by muse, mutect2, varscan2
- MTMR11 | c.1941G>T p.Q647H (on ENST00000439741 / NM_001145862.2; = p.Q575H on NM_181873.3) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54964628; called by muse, mutect2, varscan2
- MTMR2 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs752626893, COSV60578811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTMR8 | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV66392817; called by muse, mutect2, varscan2
- MTSS1 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61495485; called by muse, mutect2, varscan2
- MTUS2 | c.3098C>T p.T1033M | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs762048031, COSV70914682; called by muse, mutect2, varscan2
- MTUS2 | c.3593C>T p.T1198M (on ENST00000612955 / NM_001366650.1; = p.T177M on NM_015233.6) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs762596190, COSV66420267; called by muse, mutect2, varscan2
- MUC16 | c.11375T>A p.M3792K | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV101200131, COSV67495325; called by muse, mutect2, varscan2
- MUC17 | c.5281G>A p.V1761I | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs781393368, COSV60282413; called by muse, mutect2, varscan2
- MUC4 | c.14404G>A p.A4802T (on ENST00000463781 / NM_018406.7; = p.A566T on NM_004532.6) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.435); catalogued as rs1201925043, COSV57770407; called by muse, mutect2, varscan2
- MUSK | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 66/195 reads (34%) | catalogued as COSV51879961; called by muse, mutect2, varscan2
- MXRA5 | c.8047del p.Q2683Kfs*44 | Frame Shift Del (DEL) | VAF 86/256 reads (34%) | catalogued as COSV54244048; called by mutect2, varscan2
- MYBPH | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146696842; called by muse, mutect2, varscan2
- MYCBP2 | c.12574G>A p.A4192T (on ENST00000357337; = p.A4230T on NM_015057.5) | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1293184347, COSV62012396; called by muse, mutect2, varscan2
- MYCBP2 | c.7876G>A p.G2626R (on ENST00000357337; = p.G2664R on NM_015057.5) | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs917350267, COSV62012411; called by muse, mutect2, varscan2
- MYCBP2 | c.2429G>T p.G810V (on ENST00000357337; = p.G848V on NM_015057.5) | Missense Mutation (SNP) | VAF 58/543 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV62012426; called by muse, varscan2
- MYH3 | c.4436G>A p.S1479N | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV56862098; called by muse, mutect2, varscan2
- MYH3 | c.4148G>A p.R1383H | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs143574829; called by muse, mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 29/94 reads (31%) | catalogued as rs761123152; called by mutect2, varscan2
- MYL4 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs146980908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.928); catalogued as rs1244935895, COSV52753311; called by muse, mutect2, varscan2
- MYO15A | c.2873del p.P958Lfs*28 | Frame Shift Del (DEL) | VAF 42/150 reads (28%) | catalogued as rs1217492313; called by mutect2, pindel, varscan2
- MYO15A | c.6595G>A p.G2199S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV52753328; called by muse, mutect2, varscan2
- MYO16 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs762038297, COSV51781761; called by muse, mutect2, varscan2
- MYO16 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1186534652, COSV62746705; called by muse, mutect2, varscan2
- MYO1A | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as rs1015322457, COSV55652326; called by muse, mutect2, varscan2
- MYO1C | c.2581C>T p.R861W (on ENST00000648651 / NM_001080779.2; = p.R826W on NM_033375.5) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs368905625, COSV100704257; called by muse, mutect2, varscan2
- MYO7A | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs868923965, COSV68683826; called by muse, mutect2, varscan2
- MYO9A | c.1853A>C p.Q618P | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV61848552; called by muse, mutect2, varscan2
- MYOM1 | c.5027A>C p.E1676A | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99866981; called by muse, mutect2
- MYOM2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs144235879; called by muse, mutect2, varscan2
- MYOZ3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51739084, COSV51739602; called by muse, mutect2, varscan2
- NAA15 | c.1834A>G p.K612E | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.622); catalogued as COSV56718069; called by mutect2, varscan2
- NAA16 | c.1168T>C p.Y390H | Missense Mutation (SNP) | VAF 44/504 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV65064496; called by muse, mutect2
- NAGA | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs374542831, COSV101124134, COSV67169763; called by muse, mutect2, varscan2
- NBEA | c.6447A>T p.A2149= | Splice Region (SNP) | VAF 44/158 reads (28%) | catalogued as COSV59766949; called by muse, mutect2, varscan2
- NBEAL2 | c.4429A>G p.T1477A | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs1447408364, COSV99436254; called by muse, mutect2, varscan2
- NBEAL2 | c.6514C>T p.R2172C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52761752; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 35/101 reads (35%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCAPH | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs774780229, COSV53635427; called by muse, mutect2, varscan2
- NCKAP5L | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs576123127, COSV60128080, COSV60133529; called by muse, mutect2, varscan2
- NDST4 | c.2365A>G p.T789A | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52111937; called by muse, mutect2, varscan2
- NDUFA12 | c.67T>C p.Y23H | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV59845419, COSV59845874; called by muse, mutect2, varscan2
- NEDD9 | c.431del p.G144Efs*11 | Frame Shift Del (DEL) | VAF 99/331 reads (30%) | catalogued as rs780429523; called by mutect2, pindel, varscan2
- NEIL1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1444074667, COSV51226935; called by muse, mutect2, varscan2
- NEK5 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV62879224; called by muse, mutect2, varscan2
- NEK9 | c.1472A>G p.H491R | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs766227479, COSV53129709; called by muse, mutect2, varscan2
- NELFE | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64887221; called by muse, mutect2, varscan2
- NFE2L2 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV67960513; called by muse, mutect2
- NGLY1 | c.1129A>C p.I377L | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV54984657; called by muse, mutect2, varscan2
- NIBAN1 | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs751972614, COSV62283465; called by muse, mutect2, varscan2
- NIN | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV55382945; called by muse, mutect2, varscan2
- NIPSNAP1 | c.272+1G>A p.X91_splice | Splice Site (SNP) | VAF 37/94 reads (39%) | catalogued as COSV53342042; called by muse, mutect2, varscan2
- NLRC5 | c.4404C>A p.L1468= | Splice Region (SNP) | VAF 42/117 reads (36%) | catalogued as COSV52650710; called by muse, mutect2, varscan2
- NLRP13 | c.1629del p.F543Lfs*8 | Frame Shift Del (DEL) | VAF 39/118 reads (33%) | catalogued as rs749541198; called by mutect2, pindel, varscan2
- NLRP8 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs750103129, COSV99405398; called by muse, mutect2, varscan2
- NOC2L | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58986374; called by muse, mutect2, varscan2
- NOD2 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs199475913, COSV56048008; ClinVar: not provided; called by muse, mutect2, varscan2
- NOS1AP | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs757703119, COSV62635423; called by muse, mutect2, varscan2
- NOTCH1 | c.2860T>C p.C954R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53035069; called by muse, mutect2, varscan2
- NOXA1 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV100395591; called by muse, mutect2, varscan2
- NPBWR1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as rs183071113; called by muse, mutect2, varscan2
- NPC1L1 | c.3584T>G p.L1195R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56923206; called by muse, mutect2, varscan2
- NR1H2 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs767999123, COSV53800218; called by muse, mutect2, varscan2
- NSL1 | c.796del p.Q266Rfs*41 | Frame Shift Del (DEL) | VAF 59/192 reads (31%) | catalogued as rs1270934107; called by mutect2, pindel, varscan2
- NTRK3 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.215); catalogued as COSV58113367; called by muse, mutect2, varscan2
- NUDT7 | c.621A>C p.K207N | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as rs765225729, COSV51744329, COSV51744792; called by muse, varscan2
- NUP153 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758438447, COSV50446840; called by muse, mutect2, varscan2
- NUTM2F | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs755751887, COSV53555859; called by muse, mutect2, varscan2
- OFD1 | c.1730A>T p.N577I | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV60794809; called by muse, mutect2, varscan2
- OFD1 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV60794818; called by muse, mutect2, varscan2
- ONECUT1 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV100009276; called by muse, mutect2, varscan2
- OR10G7 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100389916; called by muse, mutect2, varscan2
- OR2T8 | c.235dup p.M79Nfs*4 | Frame Shift Ins (INS) | VAF 66/290 reads (23%) | catalogued as rs748922390; called by pindel, varscan2
- OR2T8 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as COSV60662082; called by muse, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 38/86 reads (44%) | catalogued as COSV57137289; called by mutect2, varscan2
- OR4A15 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs766456355, COSV59033991; called by muse, mutect2, varscan2
- OR4C3 | c.179dup p.L61Pfs*8 | Frame Shift Ins (INS) | VAF 71/277 reads (26%) | catalogued as rs777276396; called by mutect2, pindel, varscan2
- OR4N2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 119/360 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60050397; called by muse, mutect2, varscan2
- OR5D14 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 111/348 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV59455695, COSV59458364; called by muse, mutect2, varscan2
- OR8K1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.176); catalogued as rs369119091; called by muse, mutect2, varscan2
- OR9Q2 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.852); catalogued as rs142991971, COSV61111530; called by muse, mutect2, varscan2
- OSBPL5 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs907431268, COSV55140090; called by muse, mutect2, varscan2
- OSR2 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52555880; called by muse, mutect2, varscan2
- OTUD4 | c.2909G>C p.R970T (on ENST00000447906 / NM_001366057.1; = p.R905T on NM_001102653.1) | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.083); catalogued as COSV71381608; called by muse, mutect2, varscan2
- OXA1L | c.728T>A p.I243N (on ENST00000285848; = p.I183N on NM_005015.5) | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99591174; called by muse, mutect2
- P2RX5 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as rs954739987, COSV56591021; called by muse, mutect2, varscan2
- P2RY14 | c.244T>G p.S82A | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as COSV56371634; called by muse, mutect2, varscan2
- PABPC5 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV57039500; called by muse, mutect2, varscan2
- PACRG | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as rs749211635, COSV100433359, COSV61299053; called by muse, mutect2, varscan2
- PACSIN1 | c.1168del p.V390Cfs*97 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as COSV55059019, COSV55059382; called by mutect2, pindel, varscan2
- PAFAH2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs769270945, COSV65339115; called by muse, varscan2
- PAPLN | c.3196C>T p.R1066C (on ENST00000554301; = p.R1039C on NM_173462.4) | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs529677835, COSV53714579; called by muse, mutect2, varscan2
- PAPPA | c.4221G>T p.E1407D | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60278888; called by muse, mutect2, varscan2
- PARD6G | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62060244; called by muse, mutect2, varscan2
- PATJ | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1490845603, COSV57157433; called by muse, mutect2, varscan2
- PAX3 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1364517233, COSV60586764; called by muse, mutect2, varscan2
- PCDH19 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55259063; called by muse, varscan2
- PCDHA1 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.133); catalogued as rs782653718, COSV65372619; called by muse, mutect2, varscan2
- PCDHA10 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56483942; called by muse, mutect2, varscan2
- PCDHA5 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs781942385, COSV65350269; called by muse, mutect2, varscan2
- PCDHA7 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as rs1356053208, COSV100971536; called by muse, mutect2, varscan2
- PCDHB1 | c.1487del p.N496Tfs*12 | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | catalogued as rs782781242; called by mutect2, pindel, varscan2
- PCDHGB4 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763321545, COSV53912675; called by muse, mutect2, varscan2
- PCK2 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763930692, COSV53748192; called by muse, mutect2, varscan2
- PCM1 | c.6003G>A p.M2001I | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs1273969576, COSV59585620; called by muse, mutect2, varscan2
- PCNT | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs147670433; called by muse, mutect2, varscan2
- PCP4 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs745733374, COSV60786401; called by muse, mutect2, varscan2
- PDCD11 | c.5468A>G p.H1823R | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53294660; called by muse, mutect2, varscan2
- PDE1B | c.1565del p.P522Hfs*25 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | catalogued as rs780236743; called by mutect2, varscan2
- PDE3A | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.091); catalogued as COSV62969575, COSV62977117; called by muse, varscan2
- PDS5B | c.4142C>T p.T1381M | Missense Mutation (SNP) | VAF 130/614 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs930374554, COSV59724582; called by muse, varscan2
- PEX10 | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56579707; called by muse, mutect2, varscan2
- PHF23 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV50034915; called by muse, mutect2, varscan2
- PHRF1 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV52752469; called by muse, mutect2, varscan2
- PICALM | c.1571A>T p.N524I | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100707908; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 20/87 reads (23%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3C2G | c.1309del p.I437Yfs*5 | Frame Shift Del (DEL) | VAF 61/176 reads (35%) | catalogued as rs1377942847; called by mutect2, pindel, varscan2
- PLAG1 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57609820; called by muse, mutect2
- PLEC | c.13651C>T p.R4551C (on ENST00000322810 / NM_201380.4; = p.R4441C on NM_000445.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs200447944, COSV100515190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLOD1 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs763494719, COSV52141651; called by muse, mutect2, varscan2
- PLXNB1 | c.2452C>A p.L818M | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV56487526; called by muse, mutect2, varscan2
- PLXNB3 | c.5452C>T p.R1818C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs782313955, COSV62795982; called by muse, mutect2, varscan2
- PLXNC1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV51571064, COSV51582267; called by muse, mutect2, varscan2
- PNPT1 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 163/615 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs200555807; called by muse, mutect2, varscan2
- POLR1C | c.640T>C p.C214R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1453921181, COSV99541024; called by muse, mutect2, varscan2
- POLR1C | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99541026; called by muse, mutect2, varscan2
- POLR3C | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782255927, COSV57906837; called by muse, mutect2, varscan2
- POLRMT | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775039991, COSV52113002; called by muse, mutect2, varscan2
- POM121L12 | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as rs1264305163, COSV101374928; called by muse, mutect2, varscan2
- POMT2 | c.1472T>C p.V491A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as COSV99836464; called by muse, mutect2, varscan2
- POU4F2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55585867, COSV99850583; called by muse, mutect2, varscan2
- PPIG | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.483); catalogued as COSV53641765; called by muse, mutect2, varscan2
- PPM1N | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.18); catalogued as COSV55593002; called by muse, mutect2, varscan2
- PPP1R12C | c.1804T>A p.S602T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54736450; called by muse, mutect2, varscan2
- PPP1R13L | c.1318del p.Q440Sfs*10 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | catalogued as rs1555782094; called by mutect2, pindel, varscan2
- PPP1R1A | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV57741015; called by muse, mutect2, varscan2
- PPP1R3F | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1485410619, COSV50017825; called by muse, varscan2
- PRADC1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57819990; called by muse, mutect2, varscan2
- PRAMEF1 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as rs779715494, COSV100179654; called by muse, mutect2, varscan2
- PRG2 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs369365761; called by muse, mutect2, varscan2
- PRKCI | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.872); catalogued as rs1389006052, COSV55516956, COSV99855928; called by muse, mutect2, varscan2
- PRMT5 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV53545097; called by muse, mutect2, varscan2
- PRMT5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53545108; called by muse, mutect2, varscan2
- PRODH2 | c.1024G>A p.G342R (on ENST00000301175; = p.G266R on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs547753556, COSV56558732; called by muse, mutect2, varscan2
- PRRC2A | c.4390C>T p.R1464C | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as rs1366115537, COSV65685482; called by muse, mutect2, varscan2
- PRRC2B | c.5236C>T p.R1746C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1467351802, COSV57644554; called by muse, mutect2, varscan2
- PRUNE2 | c.4547A>G p.K1516R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs973687565, COSV65038798; called by muse, mutect2, varscan2
- PTCH1 | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769691754, COSV59466289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTDSS1 | c.394T>C p.W132R | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61263860; called by muse, mutect2, varscan2
- PTGDR2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV57124635; called by muse, mutect2, varscan2
- PTGER3 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV60688907; called by muse, mutect2, varscan2
- PTPN12 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 93/282 reads (33%) | catalogued as rs1488374923, COSV50354754; called by muse, mutect2, varscan2
- PTPRB | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as COSV51726799; called by muse, mutect2, varscan2
- PTPRF | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV63443392; called by muse, mutect2, varscan2
- PUS10 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV57450981; called by muse, mutect2, varscan2
- PWWP2A | c.1001del p.K334Rfs*25 | Frame Shift Del (DEL) | VAF 115/399 reads (29%) | catalogued as COSV61048365; called by mutect2, pindel, varscan2
- PXDNL | c.2506T>C p.C836R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62481707; called by muse, mutect2, varscan2
- PYGM | c.1402A>G p.I468V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757470750, COSV99377199; called by muse, mutect2, varscan2
- RAMP1 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54537603; called by muse, mutect2, varscan2
- RANGAP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62362670; called by muse, mutect2, varscan2
- RAPGEF2 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.982); catalogued as rs765270956, COSV52424385; called by muse, mutect2, varscan2
- RASAL1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs531834126, COSV55654427; called by muse, mutect2, varscan2
- RASGRF2 | c.2854C>T p.R952* | Nonsense Mutation (SNP) | VAF 46/160 reads (29%) | catalogued as rs1224172379, COSV54122607; called by muse, mutect2, varscan2
- RASSF6 | c.1037T>C p.F346S (on ENST00000342081 / NM_201431.2; = p.F314S on NM_177532.5) | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV56716844; called by muse, mutect2, varscan2
- RAVER1 | c.1097del p.P366Qfs*169 (on ENST00000615032; = p.P366Qfs*141 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs768618392, COSV53348646; called by mutect2, pindel, varscan2
- RBBP4 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65132150; called by muse, mutect2, varscan2
- RBM15B | c.1243A>G p.N415D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV100082188; called by muse, mutect2, varscan2
- RBSN | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227748908, COSV53791856; called by muse, mutect2, varscan2
- RCC1L | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 192/651 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs1365468101; called by muse, mutect2, varscan2
- RDX | c.419A>C p.E140A | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.779); catalogued as COSV58192415, COSV58194960; called by muse, varscan2
- RECQL4 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV52881882; called by muse, mutect2, varscan2
- REM1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV52427411; called by muse, mutect2, varscan2
- RFX3 | c.1415A>G p.N472S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs766962228, COSV56509763; called by muse, mutect2, varscan2
- RGL1 | c.653A>G p.E218G (on ENST00000360851 / NM_001297672.2; = p.E253G on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58980500; called by muse, mutect2, varscan2
- RIMBP2 | c.1680G>T p.K560N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99899681; called by muse, mutect2, varscan2
- RIMS1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53444336; called by muse, mutect2, varscan2
- RIN1 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757984197, COSV100254722; called by muse, mutect2, varscan2
- RIN3 | c.2368del p.V790Cfs*21 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | catalogued as COSV53646102; called by mutect2, pindel, varscan2
- RING1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); catalogued as COSV63002343; called by muse, mutect2, varscan2
- RINT1 | c.740del p.P247Lfs*8 | Frame Shift Del (DEL) | VAF 59/234 reads (25%) | catalogued as rs1352349454; called by mutect2, pindel, varscan2
- RNF34 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285251263, COSV63442095; called by muse, mutect2, varscan2
- RNF43 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1459309530, COSV68457734; called by muse, varscan2
- ROBO2 | c.2460_2461insT p.G821Wfs*7 | Frame Shift Ins (INS) | VAF 33/109 reads (30%) | catalogued as COSV59901256; called by mutect2, pindel, varscan2
- ROBO4 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs144947842; called by muse, mutect2, varscan2
- ROS1 | c.3300C>G p.D1100E | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV63852639; called by muse, mutect2, varscan2
- RPS6KA4 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV53701320; called by muse, mutect2, varscan2
- RPS6KA6 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99424882; called by muse, mutect2, varscan2
- RSPO1 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1337792463, COSV62973731; called by muse, mutect2, varscan2
- RTN2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV55592997; called by muse, mutect2, varscan2
- RTTN | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1357964428, COSV55342381; called by muse, mutect2, varscan2
- RTTN | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55342390; called by muse, mutect2, varscan2
- RYR1 | c.14645C>T p.T4882M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193922884, CM081417, COSV62091711; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- RYR3 | c.5465G>A p.R1822Q | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751944735, COSV66781137, COSV66782195; called by muse, mutect2, varscan2
- S1PR4 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs749842926, COSV55739559; called by mutect2, varscan2
- SAMD4B | c.1680A>G p.I560M | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV58750428; called by muse, mutect2, varscan2
- SARS1 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321321; called by muse, mutect2, varscan2
- SCARF1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs1350045146, COSV99557107; called by muse, varscan2
- SCD5 | c.289T>C p.W97R | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51102103; called by muse, mutect2, varscan2
- SCML2 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV52619102; called by muse, varscan2
- SCN10A | c.4550C>T p.A1517V | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.897); catalogued as COSV71860616; called by muse, mutect2, varscan2
- SCN11A | c.4895A>C p.K1632T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56567145; called by muse, mutect2, varscan2
- SDCBP2 | c.616G>A p.V206M (on ENST00000339987 / NM_001199784.1; = p.V121M on NM_015685.5) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs762408353, COSV60588511; called by muse, mutect2, varscan2
- SDK1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs1024397823, COSV67359779; called by muse, mutect2, varscan2
- SEC23IP | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64830955; called by muse, mutect2, varscan2
- SEC24C | c.1375dup p.Q459Pfs*17 | Frame Shift Ins (INS) | VAF 55/156 reads (35%) | catalogued as rs764652839; called by mutect2, varscan2
- SEMA3D | c.1769G>A p.S590N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV52389250; called by muse, mutect2, varscan2
- SEMA4C | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs535051646, COSV100561032; called by muse, mutect2, varscan2
- SEMA5A | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66786991; called by muse, mutect2, varscan2
- SEMA5B | c.2677G>A p.V893M | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as rs779789464, COSV52091775; called by muse, mutect2, varscan2
- SEMA6C | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 77/252 reads (31%) | catalogued as COSV59000715; called by muse, mutect2, varscan2
- SEPTIN5 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV63530439, COSV63530836; called by muse, mutect2, varscan2
- SEPTIN7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 131/401 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs761757988, COSV63254101; called by muse, mutect2, varscan2
- SF3B1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1360040192, COSV59209483; called by muse, mutect2, varscan2
- SFSWAP | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs376084110; called by mutect2, varscan2
- SFTPC | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1000316822, COSV59345309; called by muse, mutect2, varscan2
- SGSM1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as rs774720650, COSV68509074; called by muse, mutect2, varscan2
- SH3BP4 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV60642772; called by muse, mutect2, varscan2
- SH3PXD2A | c.1409G>A p.R470Q (on ENST00000369774 / NM_001365079.1; = p.R442Q on NM_014631.2) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.031); catalogued as rs374221356; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 40/105 reads (38%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHISA5 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs199734268, COSV56496356; called by muse, mutect2, varscan2
- SHMT2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs373156028; called by muse, mutect2, varscan2
- SHOX | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61860286; called by muse, mutect2, varscan2
- SHROOM2 | c.3721G>A p.G1241R | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780078570, COSV101098742; called by mutect2, varscan2
- SIM1 | c.378A>T p.E126D | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); catalogued as COSV53489730; called by muse, mutect2, varscan2
- SIX5 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1256009223, COSV52176164; called by muse, mutect2, varscan2
- SLC12A3 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs776351641, CM121274, COSV52633090; called by muse, mutect2, varscan2
- SLC16A3 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66429150; called by muse, mutect2, varscan2
- SLC18A2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53689026, COSV53690656, COSV53693116; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC26A3 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs756707598, COSV60639230; called by muse, mutect2, varscan2
- SLC2A14 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as rs374655537, COSV100533574, COSV61585766; called by muse, mutect2, varscan2
- SLC35F3 | c.1159A>G p.T387A (on ENST00000366617 / NM_001300845.1; = p.T456A on NM_173508.4) | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100784796; called by muse, mutect2, varscan2
- SLC36A1 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 74/225 reads (33%) | catalogued as rs1561757835, COSV99695602; called by muse, mutect2, varscan2
- SLC38A1 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs369346779; called by muse, mutect2, varscan2
- SLC39A7 | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63002340; called by muse, mutect2, varscan2
- SLC3A2 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779207226, COSV58602989; called by muse, mutect2, varscan2
- SLC41A1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1378557393, COSV65650104; called by muse, mutect2, varscan2
- SLC46A1 | c.1301T>A p.L434H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV50229290; called by muse, mutect2, varscan2
- SLC47A1 | c.135G>A p.A45= | Splice Region (SNP) | VAF 21/61 reads (34%) | catalogued as rs1169973887, COSV54499416; called by muse, mutect2, varscan2
- SLC49A3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.179); catalogued as rs770927084, COSV59139676; called by muse, mutect2, varscan2
- SLC49A4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1250385873, COSV53745852; called by muse, varscan2
- SLC4A11 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); catalogued as rs1326467127, COSV66260839; called by muse, mutect2, varscan2
- SLC4A4 | c.1412C>T p.S471L (on ENST00000264485 / NM_001098484.3; = p.S427L on NM_003759.4) | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM043580, COSV52617533; called by muse, mutect2, varscan2
- SLC5A8 | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73311089; called by muse, mutect2, varscan2
- SLC6A5 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs570442943, COSV100116312, COSV54224567; called by muse, mutect2, varscan2
- SLC6A7 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1355503005, COSV57936687; called by muse, mutect2, varscan2
- SLC7A11 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs771913516, COSV54928571; called by muse, mutect2, varscan2
- SLC7A11 | c.365C>G p.P122R | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV54928806; called by muse, mutect2, varscan2
- SLC7A3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs374563735, COSV53226623; called by muse, mutect2, varscan2
- SLC8A1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317243583, COSV100247582, COSV60473723; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLIT2 | c.467+2T>C p.X156_splice | Splice Site (SNP) | VAF 141/468 reads (30%) | catalogued as COSV56564060; called by muse, mutect2, varscan2
- SLIT2 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1244297047, COSV56563858; called by muse, mutect2, varscan2
- SLIT3 | c.3338del p.P1113Hfs*108 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs1319942034; called by mutect2, pindel, varscan2
- SLITRK2 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556943947, COSV100157838, COSV59425737; called by muse, mutect2, varscan2
- SLTM | c.2876G>A p.R959Q | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1162185099, COSV65848348; called by muse, mutect2, varscan2
- SMARCA1 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1342799293, COSV64411153; called by muse, mutect2, varscan2
- SMC1B | c.2419del p.R807Dfs*2 | Frame Shift Del (DEL) | VAF 95/324 reads (29%) | catalogued as COSV62528384; called by mutect2, pindel, varscan2
- SMCHD1 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs1428385394, COSV55252938; called by muse, mutect2, varscan2
- SMPD4 | c.2159G>A p.R720Q (on ENST00000409031 / NM_017951.4; = p.R691Q on NM_017751.4) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs762531432, COSV60078918; called by muse, mutect2, varscan2
- SNTG2 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs374817591; called by muse, mutect2, varscan2
- SNX1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs111801077, COSV56039530; called by mutect2, varscan2
- SON | c.4522C>T p.H1508Y | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV51652969; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 43/151 reads (28%) | catalogued as rs1278336874; called by mutect2, varscan2
- SOX13 | c.969dup p.S324Qfs*23 | Frame Shift Ins (INS) | VAF 26/108 reads (24%) | catalogued as rs774299220; called by mutect2, varscan2
- SP140 | c.1262A>G p.H421R | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59447312; called by muse, mutect2, varscan2
- SPDYC | c.119del p.G40Afs*62 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs1224705180; called by mutect2, pindel, varscan2
625 further variants in this file (313 protein-altering or splice-affecting, 286 silent, 26 other) are not listed here.
